Somatic mutation profile of tumor specimen MP2PRT-PARRTD-TMP1-A (aliquot MP2PRT-PARRTD-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARRTD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,488 days).
Specimen MP2PRT-PARRTD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 491a011b-f4dc-4853-8663-f8ace381b715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRTD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRTD-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ceb4614-6d25-44cb-aaff-54b418230472

The open-access MAF lists 100 somatic variants for this specimen: 67 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 28, Nonsense Mutation 4, Intron 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- ATRX | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 28/485 reads (6%) | catalogued as COSV64870592, COSV64871923; called by muse, mutect2
- C1QC | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 277/607 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV101009516; called by muse, mutect2, varscan2
- COL26A1 | c.994G>A p.G332S (on ENST00000313669 / NM_001278563.3; = p.G330S on NM_133457.4) | Missense Mutation (SNP) | VAF 251/558 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1388934980; called by muse, mutect2, varscan2
- COL4A3 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.138); catalogued as COSV67412540; called by muse, mutect2, varscan2
- COX7A2 | c.56T>G p.V19G | Missense Mutation (SNP) | VAF 221/770 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV57874366; called by muse, mutect2, varscan2
- CPB2 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs957075264; called by muse, mutect2
- DAB2 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 52/638 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1182217684; called by muse, mutect2
- DZANK1 | c.1453G>A p.D485N (on ENST00000262547 / NM_001099407.1; = p.D292N on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52754603; called by muse, mutect2, varscan2
- FRY | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV66564646; called by muse, mutect2, varscan2
- GREB1 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 202/466 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as rs367735341; called by muse, mutect2, varscan2
- INSYN2A | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 107/767 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs143897472; called by muse, varscan2
- KDR | c.2881C>T p.R961W | Missense Mutation (SNP) | VAF 166/666 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs530419081, COSV55759748; called by muse, mutect2, varscan2
- KRT79 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 52/754 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs767198074; called by muse, mutect2
- MOSPD3 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 144/535 reads (27%) | catalogued as rs1320292183, COSV56158630; called by muse, mutect2, varscan2
- MYO16 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779048736, COSV51821109; called by muse, mutect2, varscan2
- NRDC | c.2944G>A p.G982S | Missense Mutation (SNP) | VAF 179/375 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as COSV61405626; called by muse, mutect2, varscan2
- OR10AG1 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV56632279, COSV56634579; called by muse, mutect2, varscan2
- OR51F2 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 158/357 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs779524080; called by muse, mutect2, varscan2
- PCDHA6 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 52/828 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as rs529947844; called by muse, mutect2
- PDZRN4 | c.2719C>T p.R907* (on ENST00000402685 / NM_001164595.2; = p.R649* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 19/485 reads (4%) | catalogued as COSV54195827; called by muse, mutect2
- PKHD1 | c.7654G>T p.V2552F | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV61886741; called by muse, mutect2
- PNMA5 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 84/1290 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1323768418; called by muse, mutect2
- RIMS2 | c.808C>T p.P270S (on ENST00000666250 / NM_001348490.2; = p.P78S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs559067260; called by muse, mutect2, varscan2
- RNF133 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs113296018; called by muse, mutect2, varscan2
- ROR2 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 286/638 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs370013388; called by muse, mutect2, varscan2
- ROR2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 288/639 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as COSV65220274; called by muse, mutect2, varscan2
- TEX13A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 176/641 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV61150563, COSV61158492; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- USH2A | c.5040G>T p.K1680N | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV104407579; called by muse, mutect2, varscan2
- WWC3 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 483/1597 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs777516496; called by muse, mutect2, varscan2
- ABHD17A | c.698C>T p.A233V (on ENST00000292577 / NM_001130111.2; = p.A284V on NM_031213.4) | Missense Mutation (SNP) | VAF 160/248 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.173); called by muse, varscan2
- ANK3 | c.4394T>C p.L1465S (on ENST00000280772 / NM_001320874.2; = p.L590S on NM_001149.3) | Missense Mutation (SNP) | VAF 134/270 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- ARHGEF28 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 239/555 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ARSD | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 277/960 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ATP2A3 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 211/689 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CACNG8 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 218/454 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); called by muse, varscan2
- CAVIN2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 255/549 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CHL1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT2 | c.1201T>C p.S401P | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CNTN1 | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- COL11A1 | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CYP2A13 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 164/403 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DST | c.14731G>A p.E4911K (on ENST00000361203 / NM_001374722.1; = p.E2499K on NM_015548.5) | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- EIPR1 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 276/580 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F8 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 105/731 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FARP1 | c.906C>A p.C302* | Nonsense Mutation (SNP) | VAF 135/370 reads (36%) | called by muse, mutect2, varscan2
- FAT1 | c.9509G>A p.G3170E | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOSL2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 342/746 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, varscan2
- GABRA1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 140/291 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GCM1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 111/392 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- GRIK1 | c.2720G>A p.R907K | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- HENMT1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HOXA9 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 410/902 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, varscan2
- HOXD9 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 280/953 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMA1 | c.1100T>G p.L367R | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.944); called by muse, mutect2
- PBDC1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PNPLA7 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2
- PRKD1 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 228/683 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PRR23C | c.212T>G p.V71G | Missense Mutation (SNP) | VAF 274/604 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- RSRP1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 346/728 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SNCAIP | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 143/301 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF11L12 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 142/305 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- TRIM42 | c.404C>G p.P135R | Missense Mutation (SNP) | VAF 269/584 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VASN | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 233/811 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- XIRP2 | c.2720A>C p.Q907P (on ENST00000628543; = p.Q1082P on NM_152381.6) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- YAP1 | c.1458G>A p.M486I (on ENST00000282441 / NM_001130145.3; = p.M432I on NM_006106.5) | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADCY1 | c.3252C>A p.G1084= | Silent (SNP) | VAF 297/672 reads (44%) | catalogued as rs1440441128; called by muse, mutect2, varscan2
- AR | c.21G>A p.L7= | Silent (SNP) | VAF 369/1186 reads (31%) | called by muse, mutect2, varscan2
- ATP2A3 | c.2364C>T p.I788= | Silent (SNP) | VAF 211/684 reads (31%) | catalogued as rs1030797881, COSV59232638; called by muse, mutect2, varscan2
- ATP2C2 | c.2280C>T p.N760= | Silent (SNP) | VAF 123/437 reads (28%) | catalogued as rs373071039; called by muse, mutect2, varscan2
- C17orf113 | c.1734C>T p.A578= | Silent (SNP) | VAF 313/962 reads (33%) | called by muse, mutect2, varscan2
- CFAP47 | c.7224G>A p.G2408= | Silent (SNP) | VAF 71/450 reads (16%) | called by muse, mutect2, varscan2
- COBLL1 | c.51G>A p.R17= (on ENST00000392717; = p.R25= on NM_001278458.2) | Silent (SNP) | VAF 131/537 reads (24%) | called by muse, mutect2, varscan2
- FREM1 | c.5835C>T p.I1945= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1300449687; called by muse, varscan2
- GALNT16 | c.564G>A p.R188= | Silent (SNP) | VAF 165/577 reads (29%) | catalogued as rs1566881480; called by muse, mutect2, varscan2
- GUCY1A2 | c.903C>T p.I301= | Silent (SNP) | VAF 87/167 reads (52%) | catalogued as COSV56487431; called by muse, mutect2, varscan2
- MAN1A2 | c.1053G>A p.G351= | Silent (SNP) | VAF 34/275 reads (12%) | called by muse, mutect2, varscan2
- MAP11 | c.1062C>T p.I354= | Silent (SNP) | VAF 226/477 reads (47%) | called by muse, mutect2, varscan2
- MYO7B | c.303C>T p.I101= | Silent (SNP) | VAF 216/460 reads (47%) | called by muse, mutect2, varscan2
- NRAP | c.1959G>A p.R653= (on ENST00000359988 / NM_001322945.2; = p.R618= on NM_006175.4) | Silent (SNP) | VAF 243/656 reads (37%) | catalogued as COSV63489592; called by muse, mutect2, varscan2
- PARD6G | c.1026C>T p.D342= | Silent (SNP) | VAF 247/1455 reads (17%) | catalogued as rs1182026773; called by muse, mutect2, varscan2
- PDE3A | c.2346T>C p.H782= | Silent (SNP) | VAF 46/147 reads (31%) | called by muse, mutect2, varscan2
- PLAGL1 | c.1132C>T p.L378= | Silent (SNP) | VAF 273/906 reads (30%) | called by muse, mutect2, varscan2
- PPP1R21 | c.1638A>T p.A546= | Silent (SNP) | VAF 70/410 reads (17%) | called by muse, mutect2, varscan2
- RIPK4 | c.1956G>A p.G652= (on ENST00000352483; = p.G604= on NM_020639.3) | Silent (SNP) | VAF 396/1662 reads (24%) | called by muse, mutect2, varscan2
- SLC10A6 | c.612C>T p.L204= | Silent (SNP) | VAF 221/465 reads (48%) | catalogued as rs764001929; called by muse, mutect2, varscan2
- SLC25A43 | c.603C>T p.L201= | Silent (SNP) | VAF 175/1046 reads (17%) | catalogued as rs140156521; called by muse, mutect2, varscan2
- SLC6A6 | c.828C>T p.F276= | Silent (SNP) | VAF 223/480 reads (46%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5205G>A p.Q1735= | Silent (SNP) | VAF 258/559 reads (46%) | called by muse, mutect2, varscan2
- STAC2 | c.1221C>T p.A407= | Silent (SNP) | VAF 176/574 reads (31%) | catalogued as rs1431017029; called by muse, mutect2, varscan2
- TAS2R5 | c.222C>T p.S74= | Silent (SNP) | VAF 225/512 reads (44%) | called by muse, mutect2, varscan2
- TEX13C | c.555G>A p.A185= | Silent (SNP) | VAF 266/916 reads (29%) | catalogued as rs1254956597; called by muse, mutect2, varscan2
- TYRP1 | c.45C>T p.P15= | Silent (SNP) | VAF 129/294 reads (44%) | catalogued as COSV101141404; called by muse, mutect2, varscan2
- WDSUB1 | c.189C>T p.S63= | Silent (SNP) | VAF 22/486 reads (5%) | called by muse, mutect2
- ATP11A | c.*1117C>T | 3'UTR (SNP) | VAF 70/886 reads (8%) | called by muse, mutect2
- DSG4 | c.2138-34C>T | Intron (SNP) | VAF 115/749 reads (15%) | called by muse, mutect2, varscan2
- KCNQ2 | c.*5806G>A | 3'UTR (SNP) | VAF 171/371 reads (46%) | called by muse, mutect2, varscan2
- RAPSN | c.1166+45C>T | Intron (SNP) | VAF 293/602 reads (49%) | catalogued as rs113205822; called by muse, mutect2, varscan2
- TMEM45A | c.-4+26662G>A | Intron (SNP) | VAF 108/212 reads (51%) | catalogued as rs1278476302; called by muse, varscan2
